Surgical pathology report (de-identified scan), TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma), tissue source site Vanderbilt, specimen TCGA-VT-A80J-02A (Recurrent Tumor).

[page 1 of 2]
- Collection Date

Final Report

DIAGNOSIS:

SOFT TISSUE, LEFT THIGH, RESECTION: ONE LYMPH NODE INVOLVED BY
METASTATIC
UNDIFFERENTIATED PLEOMORPHIC SARCOMA, FNCLCC GRADE III, SIMILAR TO
PREVIOUS
; METASTATIC DEPOSIT MEASURES 3.6 CM IN GREATEST
DIMENSION;
NEGATIVE FOR EXTRANODAL EXTENSION; MARGINS NEGATIVE FOR TUMOR.

CLINICAL DATA

Clinical Diagnosis: Sarcoma / node

Operator:

Operation: Left thigh mass resection

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: Left thigh mass

Instructions to pathologist: ink not true margin.

GROSS DESCRIPTION:

1) SOURCE: Left Thigh Mass

Received fresh in a container labeled with the patient's name " " medical record number, and designated "left thigh mass" is a 25.06 g ovoid-shaped portion of soft tissue measuring 5.1 x 3.8 x 2.5 cm.

There is a 2.5 x 2.0 cm area of puckered, thin transparent membrane with suture that has previously been inked in blue, indicated as not true margin. No other orientation to the specimen is provided. The external surface is covered by a thin transparent membrane surrounding lobulated yellow fibroadipose tissue. The area previously inked blue is over-inked in

yellow and the remainder of the external surface is inked black. The specimen is serially sectioned to reveal a well-circumscribed firm, white

mass measuring 3.0 x 2.4 x 3.8 cm. There is a eccentrically located cavity

located within the mass measuring 1.0 cm in greatest dimension;

ICD O-3
Sarcoma, pleomorphic
undifferentiated (8805/3)
Code to highest 8805/3
Site: Lymph node, lower limb
077.4
Q 5/25/14

[page 2 of 2]
possibly
consistent with previous procedural site. There is a thin rim of yellow
fibroadipose tissue separating the mass from the inked surface ranging
from
0.3 to <0.1 cm. No other areas of hemorrhage or necrosis are
appreciated.
Representative sections are submitted. A portion of mass is retained in
-80
degrees for further possible studies. The remainder of the specimen is
retained in formalin within its original container.

Summary of sections:

- 1A, perpendicular section, 1 end, 1/1;
- 1B-C, 1 full-thickness cross section with closest approximation to
inked surfaces, bisected, 1/1 each;
- 1D, representative mass with close approximation to inked surface,
1/1;
- 1E, representative section of designated not true margin, 2/1;
- 1F, perpendicular section of opposite end, 1/1.

Slides and report reviewed by Attending Pathologist.

Recurrent/met for tript.

Source: NCI Genomic Data Commons file 3f2c2d42-0c97-431c-9d08-445de7819b03 (TCGA-VT-A80J.93B24C81-F289-4C93-96BC-B2D3A7D99910.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).